Somatic mutation profile of tumor specimen 0DC463 from CCDI case PBBLZF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.3 years (1,206 days).
Specimen 0DC463: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c587d89-626e-4a77-9b00-6cbeca00d9c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC461 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d54e692-0897-485a-a4c0-f9d5e017d82b

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ16 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 283/681 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766250689; called by muse, mutect2, varscan2
- TNFRSF21 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 258/604 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.727); catalogued as rs767858868; called by muse, mutect2, varscan2
- XRCC5 | c.1877C>G p.T626S | Missense Mutation (SNP) | VAF 64/1978 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV67534720; called by muse, mutect2
- ABHD15 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CCDC61 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 198/497 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM151A | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2
- GLI2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 249/939 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PVR | c.383T>A p.F128Y | Missense Mutation (SNP) | VAF 257/535 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDK4 | c.852C>T p.I284= | Silent (SNP) | VAF 584/1294 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.444C>T p.H148= | Silent (SNP) | VAF 426/911 reads (47%) | catalogued as rs750661428, COSV62143240, COSV62147854; called by muse, mutect2, varscan2
- FZD2 | c.1278C>A p.I426= | Silent (SNP) | VAF 266/596 reads (45%) | catalogued as COSV59529841; called by muse, mutect2, varscan2
- LRRTM1 | c.648C>T p.L216= | Silent (SNP) | VAF 306/1098 reads (28%) | catalogued as COSV99703260; called by muse, mutect2, varscan2
- PCDHGB4 | c.1905C>T p.A635= | Silent (SNP) | VAF 158/330 reads (48%) | catalogued as rs1437335316, COSV53949196, COSV53951944; called by muse, mutect2, varscan2
- RASSF4 | c.873G>A p.E291= | Silent (SNP) | VAF 378/889 reads (43%) | called by muse, mutect2, varscan2
- PABPC3 | c.-9G>A | 5'UTR (SNP) | VAF 82/152 reads (54%) | catalogued as rs761057217, COSV55802677; called by muse, mutect2, varscan2
- RPTOR | c.1136+70G>T | Intron (SNP) | VAF 78/188 reads (41%) | catalogued as rs1365516323, COSV100157497; called by muse, mutect2, varscan2
